CCDI case PBBVAA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/f7dc4073-37e9-46bb-b677-9cbb6c3a4215

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Adrenal cortical carcinoma: ICD-O-3 morphology code: 8370/3; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 15.0 years (5,482 days).

Biospecimens (3 samples)
- Sample 0DI3IU: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DI3JB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DI3NE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
